Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00W, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00W-01A (Primary Tumor).

Sample

Diagnosis:

- 1.: Subcapsular portion of the liver parenchyma with von Meyenburg's complex moderately developed fatty infiltration of the parenchyma.
- 2.: Resectate of a portion of the colon (sigmoid colon) with a tubulovillous colonic mucosal adenoma, extending no closer than 4.5 cm to a resection margin and measuring 1.8 cm at its greatest diameter, with severe epithelial dysplasia (synonym: high-grade intra-epithelial neoplasia) and with transitions into a moderately differentiated adenocarcinoma of the colorectal type, or colon carcinoma, fully circumferential and continuing into the internal portions of the submucosa.
- Oral and aboral resection margins tumor-free.
Seventeen mesocolic lymph nodes tumor-free with uncharacteristic reactive changes.

Tumor stage therefore pT1 pN0 (0/17) L0 V0; G2 R0.

1C0-0-3

adenocarcinoma, NOS 8140/3

Site: sigmoid colon C18.7

ju 4/1/11

Source: NCI Genomic Data Commons file b78a357d-7080-4bcd-b0d2-46b558f4a69f (TCGA-AA-A00W.57E011E8-44BE-4821-8AB0-7A4F22AC4C4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).